Somatic mutation profile of tumor specimen MBCProject_1937_T1_WES (aliquot MBCProject_1937_T1_WES_1) from CMI case MBCProject_1937, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.3 years (13,625 days).
Specimen MBCProject_1937_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f649159b-eaf1-456e-b6fa-f2b081b2a3c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1937_SALIVA (Saliva), aliquot MBCProject_1937_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcae20ea-787c-4649-8a28-2e0eb9c0fef9

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 4, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 21/157 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1204900727, COSV51643222, COSV51643797; called by muse, mutect2, varscan2
- ACACB | c.6718C>T p.R2240* | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as rs573571761, COSV100622149, COSV58130874; called by muse, mutect2, varscan2
- AGTPBP1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs146598781; called by mutect2, varscan2
- BMPR2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV101001613, COSV65812397; called by muse, mutect2, varscan2
- CSF2RA | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs747427634; called by muse, mutect2, varscan2
- CYP4F11 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs367904490; called by muse, mutect2, varscan2
- FOXP3 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs782649847; called by muse, mutect2
- MOGAT3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763000022; called by muse, mutect2, varscan2
- SEC16B | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs371931365; called by muse, mutect2, varscan2
- SHISA2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs779132447, COSV60112222; called by muse, mutect2, varscan2
- SSX2IP | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs1325307246; called by muse, mutect2, varscan2
- CDK15 | c.1184A>T p.Y395F (on ENST00000652192 / NM_001366386.2; = p.Y344F on NM_139158.2) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSFX1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.352); called by mutect2, varscan2
- LAMC1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 152/345 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACTL7B | c.84C>T p.A28= | Silent (SNP) | VAF 99/280 reads (35%) | catalogued as rs759993247; called by muse, mutect2, varscan2
- FASN | c.3324G>A p.E1108= | Silent (SNP) | VAF 201/845 reads (24%) | catalogued as COSV60752806; called by muse, mutect2, varscan2
- LRRC7 | c.3084T>C p.G1028= (on ENST00000651989 / NM_001370785.2; = p.G995= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- POLB | c.371-1049T>G | Intron (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- TUBA1A | c.3+21C>G | Intron (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6649C>T | Intron (SNP) | VAF 16/73 reads (22%) | catalogued as rs552286041, COSV57701463; called by muse, mutect2, varscan2
- YPEL2 | c.117+102T>C | Intron (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
